Somatic mutation profile of tumor specimen ALCH-ADUZ-TTP1-A (aliquot ALCH-ADUZ-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADUZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,585 days).
Specimen ALCH-ADUZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89cee01a-074a-4380-b81f-25d500dc216e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUZ-NB1-A (Blood Derived Normal), aliquot ALCH-ADUZ-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/087b1099-4ab5-4b10-86b3-d5cbb3616906

The open-access MAF lists 370 somatic variants for this specimen: 253 protein-altering or splice-affecting, 67 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 67, Intron 31, Nonsense Mutation 14, Frame Shift Del 8, RNA 6, 3'UTR 6, Splice Region 5, Splice Site 5, 5'Flank 3, 5'UTR 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 111/267 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.13451G>C p.G4484A | Missense Mutation (SNP) | VAF 69/452 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68949361; called by muse, mutect2, varscan2
- ACBD5 | c.1126G>A p.E376K (on ENST00000375888 / NM_001352568.1; = p.E367K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/543 reads (21%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV101022586; called by muse, mutect2, varscan2
- ACSM1 | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54639282; called by muse, mutect2, varscan2
- ADAT1 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 78/402 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV57189132; called by muse, mutect2, varscan2
- ADGB | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV58855321; called by muse, mutect2, varscan2
- ADGRL3 | c.3420C>A p.I1140= (on ENST00000506720 / NM_001322402.2; = p.I1072= on NM_015236.6) | Splice Region (SNP) | VAF 76/199 reads (38%) | catalogued as COSV72230149; called by muse, mutect2, varscan2
- AGTPBP1 | c.1804G>T p.D602Y (on ENST00000357081 / NM_001330701.2; = p.D562Y on NM_015239.2) | Missense Mutation (SNP) | VAF 75/449 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1174496041; called by muse, mutect2, varscan2
- ANP32E | c.602A>G p.D201G | Missense Mutation (SNP) | VAF 194/686 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.035); catalogued as COSV100029796; called by muse, mutect2, varscan2
- ARHGAP28 | c.533G>C p.S178T (on ENST00000383472 / NM_001366230.1; = p.S19T on NM_001010000.3) | Missense Mutation (SNP) | VAF 74/229 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV51646723; called by muse, mutect2, varscan2
- ARID1A | c.1570C>T p.Q524* | Nonsense Mutation (SNP) | VAF 279/986 reads (28%) | catalogued as COSV61374548; called by muse, mutect2, varscan2
- ATRX | c.6678G>C p.R2226S | Missense Mutation (SNP) | VAF 113/548 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV64873079; called by muse, mutect2, varscan2
- BRWD3 | c.4906G>A p.V1636I | Missense Mutation (SNP) | VAF 249/842 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs151186096, COSV64751960; called by muse, mutect2, varscan2
- CACNA1E | c.4102G>T p.V1368F | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV62402477; called by muse, mutect2, varscan2
- CAND1 | c.802G>T p.D268Y | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV73338604; called by muse, mutect2, varscan2
- CNTNAP5 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV101443307; called by muse, mutect2, varscan2
- COL21A1 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV55184959, COSV99777853; called by muse, mutect2, varscan2
- CRHR2 | c.917+2T>A p.X306_splice | Splice Site (SNP) | VAF 60/358 reads (17%) | catalogued as rs938752942; called by muse, mutect2, varscan2
- CSF1R | c.1221A>G p.I407M | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as rs757033979; called by muse, mutect2, varscan2
- CXorf66 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100983891; called by muse, mutect2, varscan2
- CYP27A1 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 132/435 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs755452918; called by muse, mutect2, varscan2
- DGKK | c.1944C>A p.H648Q | Missense Mutation (SNP) | VAF 73/381 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as COSV65709815; called by muse, mutect2, varscan2
- DNAJB8 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 50/288 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV59879212; called by muse, mutect2, varscan2
- EVX2 | c.1392C>A p.S464R | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as rs1364083666; called by muse, mutect2, varscan2
- F8 | c.5587-2A>C p.X1863_splice | Splice Site (SNP) | VAF 128/456 reads (28%) | catalogued as CS083226, CS0910299; called by muse, mutect2, varscan2
- FAM135B | c.954G>T p.W318C | Missense Mutation (SNP) | VAF 64/419 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425531; called by muse, mutect2, varscan2
- FLNA | c.5404G>T p.G1802C (on ENST00000369850 / NM_001110556.2; = p.G1794C on NM_001456.3) | Missense Mutation (SNP) | VAF 196/724 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100774704; called by muse, mutect2, varscan2
- FLNA | c.2193C>G p.Y731* | Nonsense Mutation (SNP) | VAF 136/509 reads (27%) | catalogued as CM098088, CM1212810; called by muse, mutect2, varscan2
- FSHR | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 95/773 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV58626179; called by muse, mutect2, varscan2
- GAGE10 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 113/416 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV101339907; called by muse, mutect2, varscan2
- GATAD2A | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs200662477; called by muse, mutect2, varscan2
- GOSR1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as rs1298435389; called by muse, mutect2, varscan2
- GPNMB | c.532C>A p.H178N | Missense Mutation (SNP) | VAF 169/573 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV51701329; called by muse, mutect2, varscan2
- GRIK3 | c.1497G>T p.Q499H | Missense Mutation (SNP) | VAF 206/660 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV66136878; called by muse, mutect2, varscan2
- GRM1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 208/634 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51110749; called by muse, mutect2, varscan2
- GTF3C1 | c.5389G>T p.G1797C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649129; called by muse, mutect2, varscan2
- HBD | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 189/523 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53082591; called by muse, mutect2, varscan2
- HHIP | c.1646del p.G549Vfs*11 | Frame Shift Del (DEL) | VAF 157/422 reads (37%) | catalogued as COSV99667686; called by mutect2, pindel, varscan2
- HIVEP2 | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 69/649 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs967871362; called by muse, mutect2, varscan2
- ITGB2 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 48/549 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100185712; called by muse, mutect2
- KIAA1210 | c.1712G>T p.G571V | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV68179481; called by muse, mutect2, varscan2
- KIF9 | c.1512C>A p.L504= | Splice Region (SNP) | VAF 32/98 reads (33%) | catalogued as COSV55519396; called by muse, varscan2
- KMT2D | c.6505G>C p.A2169P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV56412943; called by muse, mutect2, varscan2
- KRT79 | c.453C>A p.N151K | Missense Mutation (SNP) | VAF 130/397 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57940361; called by muse, mutect2, varscan2
- MARCO | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs142540932; called by muse, mutect2, varscan2
- MTG2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 55/305 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.36); catalogued as COSV63695560; called by muse, mutect2, varscan2
- MVK | c.712A>G p.K238E | Missense Mutation (SNP) | VAF 155/892 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1191193699; called by muse, mutect2, varscan2
- NCAM2 | c.2401G>T p.E801* | Nonsense Mutation (SNP) | VAF 29/143 reads (20%) | catalogued as COSV53072285, COSV53098666, COSV99525968; called by muse, mutect2, varscan2
- OAS3 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764355784; called by muse, mutect2
- OR2T8 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 89/334 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1169060768; called by muse, mutect2, varscan2
- PASD1 | c.1752G>C p.Q584H | Missense Mutation (SNP) | VAF 208/918 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100949017, COSV64856831; called by muse, mutect2, varscan2
- PCARE | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as rs760317889, COSV59054144; called by muse, mutect2
- PRR30 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as COSV53208351; called by muse, mutect2, varscan2
- RAPGEF4 | c.775G>T p.V259F | Missense Mutation (SNP) | VAF 147/487 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs376497880; called by muse, mutect2, varscan2
- RASL10A | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.193); catalogued as rs773684926; called by muse, mutect2, varscan2
- RGS5 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0.011); catalogued as COSV100008939; called by muse, mutect2, varscan2
- RYR2 | c.12568G>A p.V4190M | Missense Mutation (SNP) | VAF 153/586 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1308975705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFXN4 | c.584G>A p.W195* | Nonsense Mutation (SNP) | VAF 102/514 reads (20%) | catalogued as COSV57459819; called by muse, mutect2, varscan2
- SI | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 220/724 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.839); catalogued as COSV100014642; called by muse, mutect2, varscan2
- SIKE1 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 97/472 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1240146949; called by muse, mutect2, varscan2
- SLC39A4 | c.730C>T p.R244W (on ENST00000301305 / NM_001374839.1; = p.R219W on NM_017767.3) | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs190347138; called by muse, mutect2, varscan2
- SLFN13 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 132/506 reads (26%) | catalogued as COSV53193325; called by muse, mutect2, varscan2
- SPATA31A6 | c.3812G>A p.S1271N | Missense Mutation (SNP) | VAF 70/828 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.027); catalogued as rs779604548; called by muse, mutect2
- STYXL2 | c.2053C>T p.R685C | Missense Mutation (SNP) | VAF 90/278 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as rs370561353, COSV54811117; called by muse, mutect2, varscan2
- SYP | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 72/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV54294813; called by muse, mutect2, varscan2
- SZT2 | c.7147G>C p.A2383P (on ENST00000634258 / NM_001365999.1; = p.A2326P on NM_015284.4) | Missense Mutation (SNP) | VAF 111/366 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.907); catalogued as COSV65168201; called by muse, mutect2, varscan2
- TBC1D2 | c.2383G>T p.V795L | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV59782306, COSV59782613; called by muse, mutect2, varscan2
- TBL2 | c.1007G>T p.R336L | Missense Mutation (SNP) | VAF 63/373 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs782071345; called by muse, mutect2, varscan2
- TERT | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV57216249; called by muse, mutect2, varscan2
- TEX13C | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 210/830 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs1174656356, COSV64020770; called by muse, mutect2, varscan2
- TMLHE | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57687721; called by muse, mutect2, varscan2
- TPO | c.839C>A p.P280Q | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.456); catalogued as COSV61095304; called by muse, mutect2, varscan2
- TRPC5 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 86/297 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as COSV53297331; called by muse, mutect2, varscan2
- TTLL9 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs568245486, COSV52431327; called by muse, mutect2, varscan2
- TTN | c.24534G>C p.E8178D (on ENST00000591111; = p.E7251D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/475 reads (10%) | PolyPhen benign (0.019); catalogued as COSV100636337; called by muse, mutect2
- UBR2 | c.3587G>T p.R1196L | Missense Mutation (SNP) | VAF 82/299 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV65750622; called by muse, mutect2, varscan2
- URAD | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60380789, COSV60380964; called by muse, mutect2, varscan2
- VWDE | c.4439A>G p.Y1480C | Missense Mutation (SNP) | VAF 131/451 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51724296; called by muse, mutect2, varscan2
- ZDHHC11B | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 80/338 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.189); catalogued as rs756278131; called by muse, mutect2, varscan2
- ZNF28 | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 42/500 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs779634852, COSV60423052, COSV60424999; called by muse, mutect2
- ZNF438 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754239573, COSV100061522; called by muse, mutect2
- ZNF835 | c.412T>C p.F138L | Missense Mutation (SNP) | VAF 43/268 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV73379735; called by muse, mutect2, varscan2
- ABCG2 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ACADL | c.46C>G p.H16D | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL1 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 61/296 reads (21%) | called by muse, mutect2, varscan2
- AKR1D1 | c.331C>A p.L111I | Missense Mutation (SNP) | VAF 74/462 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- ANK2 | c.1240A>T p.M414L | Missense Mutation (SNP) | VAF 448/889 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARID4A | c.3694T>C p.S1232P | Missense Mutation (SNP) | VAF 85/398 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ATP1A4 | c.1948G>T p.V650F | Missense Mutation (SNP) | VAF 102/318 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ATP23 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 125/421 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ATRN | c.344C>A p.T115N | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, varscan2
- BAHCC1 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by mutect2, varscan2
- BCORL1 | c.2905C>A p.Q969K | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BEST2 | c.28del p.A10Rfs*37 | Frame Shift Del (DEL) | VAF 63/246 reads (26%) | called by mutect2, pindel, varscan2
- BPIFA1 | c.746G>C p.G249A | Missense Mutation (SNP) | VAF 152/477 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- BUB3 | c.871C>T p.L291F | Missense Mutation (SNP) | VAF 52/316 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C5orf24 | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 176/457 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CACNG7 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAND1 | c.3361-1G>T p.X1121_splice | Splice Site (SNP) | VAF 67/383 reads (17%) | called by muse, varscan2
- CASP3 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 81/395 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CAT | c.457T>A p.F153I | Missense Mutation (SNP) | VAF 207/523 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- CCDC110 | c.1261A>G p.T421A | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- CCDC168 | c.13880C>A p.T4627K | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CDC42EP5 | c.104A>T p.H35L | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH19 | c.1553G>A p.S518N | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- CDHR2 | c.195del p.N66Mfs*14 | Frame Shift Del (DEL) | VAF 92/274 reads (34%) | called by mutect2, pindel, varscan2
- CDK12 | c.3268G>T p.A1090S | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CEP170 | c.2865G>T p.K955N | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP3 | c.1652G>C p.C551S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- COL14A1 | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- COL5A3 | c.1945del p.Q649Rfs*66 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- COL9A1 | c.2393C>G p.P798R | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COLEC12 | c.1954-2A>T p.X652_splice | Splice Site (SNP) | VAF 39/289 reads (13%) | called by muse, mutect2, varscan2
- CREB3L3 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CRHR1 | c.230A>G p.Y77C | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTPS2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 57/317 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKK | c.3387G>C p.M1129I | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMAP1 | c.629G>T p.G210V | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- DNM1 | c.2303T>C p.V768A | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- DYNC1H1 | c.10045C>G p.P3349A | Missense Mutation (SNP) | VAF 249/598 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDC3 | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- EEF1A2 | c.905C>G p.A302G | Missense Mutation (SNP) | VAF 78/508 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ELFN1 | c.1282G>T p.G428C | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTPD4 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 211/574 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- EPB41L5 | c.709G>T p.V237F | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPOP | c.941G>A p.S314N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, varscan2
- ERICH4 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 228/670 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- F8 | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 88/349 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM71E2 | c.1996T>A p.L666M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAT3 | c.5339A>T p.E1780V | Missense Mutation (SNP) | VAF 150/279 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCN2 | c.376T>G p.C126G | Missense Mutation (SNP) | VAF 183/531 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FOXO4 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 175/677 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- FUT9 | c.310C>A p.H104N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- GPC4 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- GPR143 | c.157del p.R53Gfs*34 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- GSDMB | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 62/336 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GTDC1 | c.224_235del p.A75_P78del | In Frame Del (DEL) | VAF 54/247 reads (22%) | called by mutect2, pindel, varscan2
- HCFC1 | c.2957C>A p.T986N | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- HELZ | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 85/501 reads (17%) | called by muse, mutect2, varscan2
- HIVEP3 | c.2012T>G p.I671S | Missense Mutation (SNP) | VAF 114/672 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HPN | c.889G>T p.G297C | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- IFT80 | c.1334C>A p.A445E | Missense Mutation (SNP) | VAF 34/467 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2
- IGKV3-7 | c.83C>A p.P28Q | Missense Mutation (SNP) | VAF 168/547 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- IGKV3D-7 | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCNH2 | c.2461G>T p.D821Y | Missense Mutation (SNP) | VAF 133/437 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- KCNK6 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 157/539 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KIAA0319 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA1671 | c.5182G>T p.D1728Y | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4A | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 100/421 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- LACTBL1 | c.185G>C p.G62A (on ENST00000618559; = p.G91A on NM_001289974.2) | Missense Mutation (SNP) | VAF 111/373 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRCH2 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 49/450 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRP1B | c.10559T>C p.F3520S | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LTBP4 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 155/545 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.17744C>T p.P5915L (on ENST00000372915; = p.P3960L on NM_012090.5) | Missense Mutation (SNP) | VAF 197/683 reads (29%) | called by muse, mutect2, varscan2
- MAGEA1 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 137/555 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- MAGEA11 | c.900T>A p.D300E | Missense Mutation (SNP) | VAF 131/515 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MAGEA3 | c.-67C>A | Splice Region (SNP) | VAF 176/1202 reads (15%) | called by muse, varscan2
- MAGEB10 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 99/507 reads (20%) | called by muse, mutect2, varscan2
- MATN1 | c.607G>A p.V203M | Missense Mutation (SNP) | VAF 90/302 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD1 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- MRO | c.41C>A p.S14Y | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- MUC17 | c.5432C>A p.T1811K | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MUC21 | c.435T>G p.S145R | Missense Mutation (SNP) | VAF 338/861 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYH14 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 172/560 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2
- NBPF3 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- NEU4 | c.713A>T p.Y238F (on ENST00000391969 / NM_001167602.3; = p.Y250F on NM_080741.4) | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEXMIF | c.1873G>T p.A625S | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- NIPBL | c.7147A>T p.R2383* | Nonsense Mutation (SNP) | VAF 183/750 reads (24%) | called by muse, mutect2, varscan2
- NKTR | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NLGN3 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- NOC2L | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 169/608 reads (28%) | called by muse, mutect2, varscan2
- NOL9 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.905T>A p.M302K | Missense Mutation (SNP) | VAF 175/534 reads (33%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- NUP133 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 74/294 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- OR12D3 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 66/329 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR8G5 | c.317T>C p.V106A | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH15 | c.4823C>A p.S1608Y | Missense Mutation (SNP) | VAF 182/815 reads (22%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PCDH15 | c.1616G>C p.G539A | Missense Mutation (SNP) | VAF 80/454 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB4 | c.1958C>T p.A653V | Missense Mutation (SNP) | VAF 221/490 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- PCDHB8 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 412/1622 reads (25%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PDE6C | c.1936A>T p.S646C | Missense Mutation (SNP) | VAF 79/419 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- PDHA2 | c.773T>A p.L258Q | Missense Mutation (SNP) | VAF 94/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDK3 | c.307C>A p.Q103K | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFAS | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- PFKL | c.792G>T p.E264D | Missense Mutation (SNP) | VAF 120/445 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIK3R4 | c.1211A>C p.H404P | Missense Mutation (SNP) | VAF 36/682 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2
- PLCB1 | c.1008A>T p.T336= | Splice Region (SNP) | VAF 33/181 reads (18%) | called by muse, varscan2
- PLCG2 | c.3059A>T p.Y1020F | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.079); called by muse, mutect2
- PLCXD3 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 112/355 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLXNA4 | c.1753C>A p.P585T | Missense Mutation (SNP) | VAF 63/330 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PLXNC1 | c.3250A>C p.R1084= | Splice Region (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- PNMA2 | c.173A>G p.K58R | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRMT8 | c.1101+1del | Frame Shift Del (DEL) | VAF 89/331 reads (27%) | called by mutect2, pindel, varscan2
- PRSS55 | c.581G>A p.W194* | Nonsense Mutation (SNP) | VAF 81/189 reads (43%) | called by muse, mutect2, varscan2
- PTGER4 | c.1078G>T p.G360* | Nonsense Mutation (SNP) | VAF 111/467 reads (24%) | called by muse, mutect2, varscan2
- PTPRS | c.2440A>G p.M814V | Missense Mutation (SNP) | VAF 81/400 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- RAB40A | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 177/763 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RABGAP1L | c.1051G>T p.A351S (on ENST00000489615 / NM_001243765.2; = p.A234S on NM_001243764.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/479 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- RB1 | c.1351_1359del p.R451_Y453del | In Frame Del (DEL) | VAF 136/505 reads (27%) | called by mutect2, pindel, varscan2
- RBM46 | c.181T>A p.C61S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.067); called by muse, varscan2
- RYR2 | c.6239T>C p.L2080P | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SBK3 | c.336dup p.Y113Lfs*55 | Frame Shift Ins (INS) | VAF 56/223 reads (25%) | called by mutect2, pindel, varscan2
- SGO2 | c.1440A>C p.E480D | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHC2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- SHROOM2 | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- SLC38A11 | c.817G>T p.G273C (on ENST00000409149 / NM_001351539.1; = p.G251C on NM_173512.2) | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SLC46A2 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC9C2 | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 36/710 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.432); called by muse, mutect2
- SON | c.5564A>G p.K1855R | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SPATA31A3 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 251/1669 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- STK36 | c.1568G>T p.W523L | Missense Mutation (SNP) | VAF 82/261 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- STMN3 | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 78/273 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAB3 | c.204A>T p.R68S | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TARBP1 | c.3830A>C p.Q1277P | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2
- TBC1D16 | c.561G>T p.L187F | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TBR1 | c.1927G>T p.A643S | Missense Mutation (SNP) | VAF 98/330 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBX20 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 221/586 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TECTB | c.886G>T p.V296F | Missense Mutation (SNP) | VAF 53/253 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- TENT5A | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- THBD | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.4810G>A p.G1604R (on ENST00000272643; = p.G1602R on NM_001316349.2) | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM143 | c.673A>G p.T225A | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TOX2 | c.629C>T p.P210L (on ENST00000358131 / NM_001098798.2; = p.P159L on NM_032883.3) | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TP53 | c.778_782+19del p.X260_splice | Splice Site (DEL) | VAF 71/240 reads (30%) | called by mutect2, pindel, varscan2
- TPD52L3 | c.118G>T p.E40* | Nonsense Mutation (SNP) | VAF 253/751 reads (34%) | called by muse, mutect2, varscan2
- TRAV19 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TRPA1 | c.1358del p.A453Efs*17 | Frame Shift Del (DEL) | VAF 247/720 reads (34%) | called by mutect2, varscan2
- TTN | c.40796G>T p.W13599L (on ENST00000591111; = p.W6175L on NM_003319.4) | Missense Mutation (SNP) | VAF 226/714 reads (32%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.33799C>T p.P11267S (on ENST00000591111; = p.P10340S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/116 reads (14%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.29519G>T p.G9840V (on ENST00000591111; = p.G8913V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/358 reads (7%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.29518G>T p.G9840C (on ENST00000591111; = p.G8913C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/358 reads (7%) | PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.9350C>A p.P3117Q (on ENST00000591111; = p.P3071Q on NM_003319.4) | Missense Mutation (SNP) | VAF 91/521 reads (17%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TXK | c.470G>T p.R157I | Missense Mutation (SNP) | VAF 136/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBAC1 | c.1147A>T p.M383L | Missense Mutation (SNP) | VAF 145/474 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBAP1L | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- UCK2 | c.528G>T p.R176S | Missense Mutation (SNP) | VAF 114/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- UNC13A | c.2337G>A p.M779I | Missense Mutation (SNP) | VAF 106/306 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- URB1 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, varscan2
- USP11 | c.2237A>T p.D746V (on ENST00000218348; = p.D703V on NM_001371072.1) | Missense Mutation (SNP) | VAF 46/288 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WIZ | c.5577del p.H1860Tfs*5 (on ENST00000673675 / NM_001371589.1; = p.H765Tfs*5 on NM_021241.3) | Frame Shift Del (DEL) | VAF 57/377 reads (15%) | called by mutect2, pindel, varscan2
- WNK2 | c.5948G>C p.R1983P (on ENST00000297954 / NM_001282394.1; = p.R1946P on NM_006648.3) | Missense Mutation (SNP) | VAF 75/627 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XAB2 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- XKR8 | c.1077T>G p.S359R | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.2308C>G p.P770A | Missense Mutation (SNP) | VAF 86/506 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, varscan2
- ZDHHC6 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ZFHX4 | c.5310G>A p.M1770I | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- ZFHX4 | c.9436C>A p.P3146T | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, varscan2
- ZFR | c.2153G>T p.R718L | Missense Mutation (SNP) | VAF 86/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZFYVE16 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ZNF521 | c.2320A>T p.N774Y | Missense Mutation (SNP) | VAF 198/548 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ZNF676 | c.563T>A p.L188Q (on ENST00000650058; = p.L156Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 139/489 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF831 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZNF878 | c.1495A>T p.R499W | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- ADGB | c.912C>A p.A304= | Silent (SNP) | VAF 67/210 reads (32%) | called by muse, mutect2, varscan2
- APOBEC4 | c.660G>A p.L220= | Silent (SNP) | VAF 104/336 reads (31%) | called by muse, mutect2
- BBS12 | c.870A>T p.V290= | Silent (SNP) | VAF 134/266 reads (50%) | called by muse, mutect2, varscan2
- BCAR1 | c.1203T>C p.D401= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, varscan2
- BMP7 | c.720G>T p.R240= | Silent (SNP) | VAF 99/558 reads (18%) | catalogued as rs1472375458, COSV101215858; called by muse, mutect2, varscan2
- C12orf42 | c.66A>T p.A22= | Silent (SNP) | VAF 60/372 reads (16%) | called by muse, mutect2, varscan2
- CACNA2D3 | c.1917G>T p.L639= | Silent (SNP) | VAF 54/206 reads (26%) | catalogued as COSV99877079; called by muse, mutect2, varscan2
- CDH11 | c.2097G>A p.E699= | Silent (SNP) | VAF 51/251 reads (20%) | called by muse, mutect2, varscan2
- CDHR1 | c.585G>T p.G195= | Silent (SNP) | VAF 129/606 reads (21%) | called by muse, mutect2, varscan2
- CDYL2 | c.465G>A p.G155= | Silent (SNP) | VAF 73/389 reads (19%) | called by muse, mutect2, varscan2
- CEACAM8 | c.60C>T p.L20= | Silent (SNP) | VAF 51/219 reads (23%) | called by muse, mutect2, varscan2
- CPA2 | c.6C>T p.A2= | Silent (SNP) | VAF 128/423 reads (30%) | called by muse, mutect2, varscan2
- CTDP1 | c.747C>T p.S249= | Silent (SNP) | VAF 199/598 reads (33%) | called by muse, mutect2, varscan2
- DMXL1 | c.6030A>G p.T2010= | Silent (SNP) | VAF 114/310 reads (37%) | catalogued as rs1163769405; called by muse, mutect2, varscan2
- EIF1B | c.288T>C p.F96= | Silent (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- FAM135B | c.3603C>T p.H1201= | Silent (SNP) | VAF 94/331 reads (28%) | called by muse, mutect2, varscan2
- FBP1 | c.900G>A p.K300= | Silent (SNP) | VAF 94/555 reads (17%) | catalogued as COSV64690056; called by muse, mutect2, varscan2
- FGFR1 | c.2106C>G p.P702= (on ENST00000447712 / NM_023110.3; = p.P700= on NM_015850.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/463 reads (16%) | called by muse, mutect2, varscan2
- FRMPD1 | c.4170C>A p.T1390= | Silent (SNP) | VAF 90/223 reads (40%) | called by muse, mutect2, varscan2
- FTCDNL1 | c.222C>A p.R74= | Silent (SNP) | VAF 66/422 reads (16%) | called by muse, mutect2, varscan2
- GDPD2 | c.1002G>A p.T334= | Silent (SNP) | VAF 83/319 reads (26%) | catalogued as rs759072212; called by muse, mutect2, varscan2
- GOLGA8M | c.1050T>C p.L350= | Silent (SNP) | VAF 222/983 reads (23%) | called by muse, varscan2
- GRIN3A | c.72G>T p.V24= | Silent (SNP) | VAF 124/711 reads (17%) | called by muse, mutect2, varscan2
- HCFC1 | c.669G>T p.G223= | Silent (SNP) | VAF 134/474 reads (28%) | called by muse, mutect2, varscan2
- HK3 | c.2424C>T p.A808= | Silent (SNP) | VAF 54/101 reads (53%) | called by muse, mutect2, varscan2
- IGKV1-33 | c.210C>A p.I70= | Silent (SNP) | VAF 106/527 reads (20%) | called by muse, varscan2
- IGKV1-9 | c.18C>T p.P6= | Silent (SNP) | VAF 55/517 reads (11%) | catalogued as rs569206745; called by muse, mutect2, varscan2
- IGSF21 | c.132G>A p.L44= | Silent (SNP) | VAF 112/447 reads (25%) | catalogued as COSV52138452; called by muse, mutect2, varscan2
- IRS2 | c.2796G>T p.S932= | Silent (SNP) | VAF 36/60 reads (60%) | called by muse, mutect2, varscan2
- JADE2 | c.726G>T p.L242= | Silent (SNP) | VAF 44/123 reads (36%) | called by muse, mutect2, varscan2
- KBTBD8 | c.1269T>C p.T423= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as rs764213232; called by muse, mutect2, varscan2
- KMT2D | c.1782G>T p.P594= | Silent (SNP) | VAF 219/662 reads (33%) | called by muse, mutect2, varscan2
- LINGO2 | c.1275G>A p.G425= | Silent (SNP) | VAF 51/289 reads (18%) | catalogued as rs760521373; called by muse, mutect2, varscan2
- LRFN4 | c.333G>A p.L111= | Silent (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- MAGEB6B | c.1164A>C p.P388= | Silent (SNP) | VAF 40/199 reads (20%) | called by muse, mutect2, varscan2
- MAGEL2 | c.1875C>T p.H625= | Silent (SNP) | VAF 106/244 reads (43%) | called by muse, mutect2, varscan2
- MCF2 | c.1089C>A p.L363= | Silent (SNP) | VAF 48/249 reads (19%) | catalogued as COSV58478036; called by muse, mutect2, varscan2
- MEIOC | c.1101C>T p.T367= | Silent (SNP) | VAF 47/293 reads (16%) | catalogued as COSV100740306; called by muse, varscan2
- METTL11B | c.375C>A p.S125= | Silent (SNP) | VAF 212/675 reads (31%) | catalogued as COSV63030163; called by muse, mutect2, varscan2
- NR3C2 | c.2460A>G p.K820= | Silent (SNP) | VAF 333/555 reads (60%) | catalogued as COSV100679026; called by muse, mutect2, varscan2
- NR4A3 | c.1014G>A p.K338= | Silent (SNP) | VAF 50/410 reads (12%) | called by muse, mutect2, varscan2
- NXNL1 | c.315T>C p.D105= | Silent (SNP) | VAF 30/160 reads (19%) | called by muse, mutect2, varscan2
- OGDHL | c.2793A>G p.A931= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- OR10A7 | c.630C>T p.P210= | Silent (SNP) | VAF 61/535 reads (11%) | catalogued as rs193164210; called by muse, mutect2, varscan2
- OR6C2 | c.660C>A p.V220= | Silent (SNP) | VAF 54/384 reads (14%) | called by muse, mutect2, varscan2
- OTOGL | c.3820T>C p.L1274= (on ENST00000547103; = p.L1265= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2
- PCDH1 | c.3234A>G p.R1078= | Silent (SNP) | VAF 73/176 reads (41%) | called by muse, mutect2, varscan2
- PDZD4 | c.1512G>C p.R504= | Silent (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- PERM1 | c.1888C>A p.R630= | Silent (SNP) | VAF 82/249 reads (33%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1752C>A p.V584= | Silent (SNP) | VAF 59/317 reads (19%) | catalogued as COSV100325227; called by muse, mutect2, varscan2
- PRAG1 | c.1986C>T p.P662= | Silent (SNP) | VAF 129/307 reads (42%) | called by muse, mutect2, varscan2
- PTPRM | c.159C>T p.T53= | Silent (SNP) | VAF 146/439 reads (33%) | called by muse, mutect2, varscan2
- RABEP1 | c.1425A>T p.A475= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- RPS6KB2 | c.591C>T p.P197= | Silent (SNP) | VAF 58/167 reads (35%) | catalogued as rs772031702; called by muse, mutect2, varscan2
- SELP | c.1650A>G p.E550= | Silent (SNP) | VAF 94/301 reads (31%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.1293G>A p.K431= | Silent (SNP) | VAF 48/188 reads (26%) | called by muse, mutect2, varscan2
- SERPINA3 | c.267G>A p.L89= | Silent (SNP) | VAF 187/494 reads (38%) | catalogued as COSV101261670; called by muse, mutect2, varscan2
- SI | c.180A>G p.S60= | Silent (SNP) | VAF 172/518 reads (33%) | called by muse, mutect2, varscan2
- SLC22A16 | c.1224C>T p.A408= | Silent (SNP) | VAF 109/308 reads (35%) | called by muse, mutect2, varscan2
- SLC44A5 | c.1092T>A p.I364= | Silent (SNP) | VAF 76/278 reads (27%) | called by muse, mutect2, varscan2
- SLFNL1 | c.87C>A p.P29= | Silent (SNP) | VAF 141/446 reads (32%) | catalogued as rs549710394, COSV57235660; called by muse, mutect2, varscan2
- SLITRK4 | c.556C>A p.R186= | Silent (SNP) | VAF 76/286 reads (27%) | called by muse, mutect2, varscan2
- SPTA1 | c.2946C>A p.V982= | Silent (SNP) | VAF 158/526 reads (30%) | catalogued as COSV63749055, COSV63750775; called by muse, mutect2, varscan2
- TBR1 | c.1926G>T p.P642= | Silent (SNP) | VAF 99/336 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.15603C>T p.G5201= (on ENST00000591111; = p.G4274= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/192 reads (34%) | catalogued as rs778313904; called by muse, mutect2, varscan2
- ZNF585A | c.798C>A p.G266= (on ENST00000292841 / NM_001288800.2; = p.G211= on NM_152655.3) | Silent (SNP) | VAF 47/624 reads (8%) | called by muse, mutect2
- ZNF831 | c.699G>A p.R233= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- AC133065.1 | n.439-1465G>A | Intron (SNP) | VAF 54/230 reads (23%) | catalogued as rs776905914; called by muse, mutect2, varscan2
- AMPH | c.1182+1242G>C | Intron (SNP) | VAF 108/311 reads (35%) | catalogued as COSV100343337; called by muse, mutect2, varscan2
- ANKZF1 | c.149-83T>A | Intron (SNP) | VAF 44/165 reads (27%) | called by muse, mutect2, varscan2
- ARGLU1 | c.573+187G>T | Intron (SNP) | VAF 163/333 reads (49%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-4242G>T | Intron (SNP) | VAF 154/577 reads (27%) | called by muse, mutect2, varscan2
- ARSA | c.*45G>T | 3'UTR (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- BAZ1A | c.537-5815C>T | Intron (SNP) | VAF 46/293 reads (16%) | called by muse, mutect2, varscan2
- BLOC1S6 | c.225-5165T>A | Intron (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- BRWD3 | c.2231+50G>T | Intron (SNP) | VAF 76/254 reads (30%) | called by muse, mutect2, varscan2
- CDC123 | c.*155dup | 3'UTR (INS) | VAF 24/126 reads (19%) | called by mutect2, varscan2
- CHMP2B | c.425-42G>T | Intron (SNP) | VAF 78/272 reads (29%) | catalogued as rs756914093; called by muse, mutect2, varscan2
- DNAH10 | c.1816-2580G>T | Intron (SNP) | VAF 68/203 reads (33%) | called by muse, varscan2
- DNMT1 | c.2847-51A>T | Intron (SNP) | VAF 136/478 reads (28%) | called by muse, mutect2, varscan2
- GLUD2 | c.-6G>C | 5'UTR (SNP) | VAF 25/83 reads (30%) | called by mutect2, varscan2
- HCFC1 | c.4498-22C>A | Intron (SNP) | VAF 115/453 reads (25%) | called by muse, mutect2, varscan2
- IAPP | c.80+237C>A | Intron (SNP) | VAF 57/187 reads (30%) | called by muse, mutect2, varscan2
- KATNIP | c.*9G>A | 3'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- KYAT3 | c.453+189C>G | Intron (SNP) | VAF 50/175 reads (29%) | called by muse, mutect2, varscan2
- LTBP1 | c.1034-324G>T | Intron (SNP) | VAF 55/418 reads (13%) | called by muse, mutect2, varscan2
- LYPD3 | c.383-144C>T | Intron (SNP) | VAF 90/338 reads (27%) | called by muse, mutect2
- MIR508 | n.75dup | RNA (INS) | VAF 100/374 reads (27%) | called by pindel, varscan2
- MIR508 | n.22G>T | RNA (SNP) | VAF 142/434 reads (33%) | called by muse, varscan2
- MPZ | chr1:161309960 C>A | 5'Flank (SNP) | VAF 24/88 reads (27%) | called by muse, varscan2
- MUC19 | c.516+12G>A | Intron (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2
- NOC2LP2 | n.951C>G | RNA (SNP) | VAF 96/699 reads (14%) | called by muse, mutect2, varscan2
- NT5DC3 | chr12:103841541 G>C | 5'Flank (SNP) | VAF 74/344 reads (22%) | called by muse, mutect2, varscan2
- PDE4C | c.-209-100G>T | Intron (SNP) | VAF 54/235 reads (23%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.46-705G>T | Intron (SNP) | VAF 68/221 reads (31%) | called by muse, mutect2, varscan2
- PIPSL | n.1355C>A | RNA (SNP) | VAF 53/304 reads (17%) | called by muse, mutect2, varscan2
- PITX2 | c.185-959C>A | Intron (SNP) | VAF 325/619 reads (53%) | catalogued as rs769617540; called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65762C>A | Intron (SNP) | VAF 65/416 reads (16%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.-7A>C | 5'UTR (SNP) | VAF 176/564 reads (31%) | called by muse, mutect2, varscan2
- RFPL4AP1 | n.608C>T | RNA (SNP) | VAF 248/900 reads (28%) | called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163841 C>A | 5'Flank (SNP) | VAF 16/300 reads (5%) | catalogued as rs1445904542; called by muse, mutect2
- SEC1P | n.604C>T | RNA (SNP) | VAF 127/422 reads (30%) | catalogued as rs762401617; called by muse, mutect2, varscan2
- SLC6A8 | c.778-39G>T | Intron (SNP) | VAF 178/521 reads (34%) | catalogued as rs782063195; called by muse, mutect2, varscan2
- SLIT3 | c.1459+4572G>T | Intron (SNP) | VAF 152/348 reads (44%) | called by muse, mutect2, varscan2
- STK11IP | c.946-29A>T | Intron (SNP) | VAF 74/267 reads (28%) | called by muse, mutect2, varscan2
- SUN1 | c.659-381A>G | Intron (SNP) | VAF 50/127 reads (39%) | called by muse, mutect2, varscan2
- TES | c.1077+78A>G | Intron (SNP) | VAF 51/355 reads (14%) | called by muse, mutect2, varscan2
- THY1 | c.*80C>T | 3'UTR (SNP) | VAF 61/145 reads (42%) | called by muse, mutect2, varscan2
- TNFRSF4 | c.269-177G>T | Intron (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- TTC14 | c.858-42del | Intron (DEL) | VAF 22/171 reads (13%) | called by mutect2, pindel, varscan2
- TTC21B | c.*18G>C | 3'UTR (SNP) | VAF 176/569 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.10360+3231del | Intron (DEL) | VAF 86/733 reads (12%) | catalogued as COSV59902704; called by mutect2, pindel, varscan2
- U8 | chr15:30113947 A>G | 3'Flank (SNP) | VAF 63/291 reads (22%) | called by muse, mutect2, varscan2
- UTP14A | c.-26C>T | 5'UTR (SNP) | VAF 139/609 reads (23%) | called by muse, mutect2, varscan2
- WASHC3 | c.151-4169G>T | Intron (SNP) | VAF 24/220 reads (11%) | called by mutect2, varscan2
- WNK4 | c.2295+130_2295+131insAT | Intron (INS) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- ZNF99 | c.*596G>T | 3'UTR (SNP) | VAF 112/434 reads (26%) | called by muse, varscan2
